Somatic mutation profile of tumor specimen TCGA-EJ-A8FO-01A (aliquot TCGA-EJ-A8FO-01A-21D-A364-08) from TCGA case TCGA-EJ-A8FO, project TCGA-PRAD (Prostate Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Prostate gland; Age at diagnosis: 51.7 years (18,875 days).
Specimen TCGA-EJ-A8FO-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) bbc90ee5-6f06-4446-8690-0b6fee96d5c0.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-EJ-A8FO-10A (Blood Derived Normal), aliquot TCGA-EJ-A8FO-10A-01D-A362-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/0995ca47-6333-424a-ab03-783f30017e1f

The open-access MAF lists 12 somatic variants for this specimen: 10 protein-altering or splice-affecting, 2 silent.
By variant classification: Missense Mutation 10, Silent 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ATP12A | c.1334G>A p.R445Q | Missense Mutation (SNP) | VAF 22/159 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.547); catalogued as rs769564297, COSV99516935, COSV99517190; called by muse, mutect2, varscan2
- ATP5MC3 | c.332A>G p.Q111R | Missense Mutation (SNP) | VAF 7/66 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.974); catalogued as COSV99507041; called by muse, mutect2, varscan2
- EEF2K | c.799G>A p.G267S | Missense Mutation (SNP) | VAF 5/38 reads (13%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.859); catalogued as rs371880159; called by muse, mutect2, varscan2
- GJA8 | c.199G>A p.D67N | Missense Mutation (SNP) | VAF 14/58 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs782805555, COSV53789424; called by muse, mutect2, varscan2
- GSTO1 | c.249C>G p.I83M | Missense Mutation (SNP) | VAF 15/60 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs760498687, COSV100866900, COSV63846794; called by muse, mutect2, varscan2
- MORN4 | c.85G>A p.G29S | Missense Mutation (SNP) | VAF 14/95 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100167255; called by muse, mutect2, varscan2
- NCAN | c.1939C>A p.P647T | Missense Mutation (SNP) | VAF 3/50 reads (6%) | SIFT deleterious (0.01); PolyPhen benign (0.037); catalogued as COSV99386473; called by muse, mutect2
- OPCML | c.724C>A p.L242M | Missense Mutation (SNP) | VAF 3/40 reads (8%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.98); catalogued as COSV100097591; called by muse, mutect2
- PEAK1 | c.4907G>A p.R1636Q | Missense Mutation (SNP) | VAF 6/30 reads (20%) | SIFT tolerated (0.6); PolyPhen benign (0); catalogued as rs200619883, COSV56931103; called by muse, mutect2, varscan2
- TEKT5 | c.1211T>G p.M404R | Missense Mutation (SNP) | VAF 14/110 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.319); catalogued as COSV99295789; called by muse, mutect2, varscan2
- MYH2 | c.4407G>A p.T1469= | Silent (SNP) | VAF 9/52 reads (17%) | catalogued as rs144654838; ClinVar: likely benign; called by muse, mutect2, varscan2
- SOAT1 | c.519C>A p.L173= | Silent (SNP) | VAF 9/53 reads (17%) | catalogued as COSV100858865; called by muse, mutect2
